Gene-level copy-number profile of tumor specimen TCGA-N9-A4Q7-01A from TCGA case TCGA-N9-A4Q7, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IA; Age at diagnosis: 69.6 years (25,419 days).
Specimen TCGA-N9-A4Q7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.7c8784ea-f79d-40ee-90db-1c01f146a7fc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N9-A4Q7-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e4225aeb-9e58-4682-aef0-8e5e72d150bb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 11,928; copy number 2: 24,966; copy number 3: 20,318; copy number 4: 1,595; copy number 5: 925; copy number 6: 43; copy number 7: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N9-A4Q7-01A-11D-A28Q-01): tumor purity 0.32, ploidy 3.76, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:71,395,943–72,282,539, 4 genes (within-gene range 0–3): NEGR1, AL354949.1, AL359821.1, NEGR1-IT1.
- chr2:140,683,360–141,208,376, 5 genes: COPRSP1, LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,004 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:155,018,520–155,331,114, 32 genes, copy number 7 (within-gene range 4–7): DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1.
- chr1:155,346,350–155,419,500, 4 genes, copy number 7: MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P.
- chr7:80,662,331–80,662,585, 1 gene, copy number 5: AC073850.1.
- chr11:63,938,959–64,532,970, 43 genes, copy number 6: NAA40, RNU6-45P, COX8A, AP000721.1, OTUB1, MACROD1, AP000721.2, AP006333.2, FLRT1, AP006333.1, STIP1, FERMT3, TRPT1, NUDT22, AP001453.1, DNAJC4, VEGFB, FKBP2, AP001453.3, PPP1R14B, PPP1R14B-AS1, AP001453.2, PLCB3, BAD, GPR137, KCNK4, KCNK4-TEX40, Y_RNA, CATSPERZ, ESRRA, TRMT112, PRDX5, AP003774.2, CCDC88B, MIR7155, RPS6KA4, MIR1237, LINC02723, AP003774.1, LINC02724, AP005273.2, AP005273.1, AP006288.1.
- chr15:19,878,555–30,991,628, 429 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr15:42,939,310–55,508,234, 297 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr15:92,617,448–92,809,884, 1 gene, copy number 5 (within-gene range 1–5): FAM174B.
- chr15:92,699,040–101,933,350, 197 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,928. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
